Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A964, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A964-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: max. 12.5 cm

infiltration of lung and pericard

Diagnosis:

Atypical Type A-Thymoma

pT3, pNx, pM1 (lung)

Masaoka-Koga: IVb

Immunohistochemistry

epithelial cells positive for: CK5/6, KL1, p63

epithelial cells negative for: CD1a, CD3, CD20, chromogranin A, NSE,
synaptophysin, bHCG, AFP, PLAP, CD56, CD30

some CD5-, CD117-positive T-lymphocytes

no positive TdT cells

ICD O-3
Thymoma, type A, malignant
8581/3
Site Anterior mediastinum
C38.1
4/7/14

Source: NCI Genomic Data Commons file 6f124590-5283-4d72-864c-ad97d4426bb6 (TCGA-ZB-A964.1116C97B-EE28-4073-9E05-C6E28689B9B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).